Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A0LO, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A0LO-01A (Primary Tumor).

[page 1 of 2]
Specimens Submitted:

- 1: SP: Uterus, cervix, bilateral tubes and ovaries (
- 2: SP: Right para-aortic lymph node
- 3: SP: Left para-aortic lymph node (
- 4: SP: Right common iliac lymph node
- 5: SP: Left common iliac lymph node (
- 6: SP: Left external iliac lymph node
- 7: SP: Left internal iliac lymph node
- 8: SP: Left obturator lymph node
- 9: SP: Left hypogastric lymph node
- 10: SP: Right obturator lymph node
- 11: SP: Right hypogastric lymph node
- 12: SP: Right external iliac lymph node

ICD-0-3

adenocarcinoma, endometrioid, nos 8380/3
Site: Endometrium c54.1

lw
5/1/11

DIAGNOSIS:

- 1) UTERUS, OVARIES, FALLOPIAN TUBES; TOTAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:
- ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID TYPE, NOS, FIGO GRADE 2, NUCLEAR GRADE 2.
- THE TUMOR IS LIMITED TO THE ENDOMETRIUM.
- NO ENDOCERVICAL INVASION IS IDENTIFIED.
- NO VASCULAR INVASION IS IDENTIFIED.
- THE ENDOMETRIUM SHOWS THE FOLLOWING ABNORMALITY: COMPLEX HYPERPLASIA WITH ATYPIA.
- THE MYOMETRIUM SHOWS THE FOLLOWING ABNORMALITY: ADENOMYOSIS.
- THE LEFT OVARY SHOWS SURFACE ADHESIONS.
- ALL OTHER ADNEXAE ARE UNREMARKABLE.
- 2) LYMPH NODES, RIGHT PARA-AORTIC; BIOPSY:
- THREE BENIGN LYMPH NODES (0/3).
- 3) LYMPH NODES, LEFT PARA-AORTIC; BIOPSY:
- THREE BENIGN LYMPH NODES (0/3).
- 4) LYMPH NODES, RIGHT COMMON ILIAC; BIOPSY:
- BENIGN ADIPOSE TISSUE.

** Continued on next page **

[page 2 of 2]
Page 2 of 6

- NO LYMPH NODES ARE IDENTIFIED IN THE ENTIRELY SUBMITTED SPECIMEN.
- 5) LYMPH NODES, LEFT COMMON ILIAC; BIOPSY:
- TWO BENIGN LYMPH NODES (0/2).
- 6) LYMPH NODES, LEFT EXTERNAL ILIAC; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 7) LYMPH NODES, LEFT INTERNAL ILIAC; BIOPSY:
- BENIGN ADIPOSE TISSUE.
- NO LYMPH NODES ARE IDENTIFIED IN THE ENTIRELY SUBMITTED SPECIMEN.
- 8) LYMPH NODES, LEFT OBTURATOR; BIOPSY:
- THREE BENIGN LYMPH NODES (0/3).
- 9) LYMPH NODES, LEFT HYPOGASTRIC; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 10) LYMPH NODES, RIGHT OBTURATOR; BIOPSY:
- SIX BENIGN LYMPH NODES (0/6).
- 11) LYMPH NODES, RIGHT HYPOGASTRIC; BIOPSY:
- TWO BENIGN LYMPH NODES (0/2).
- 12) LYMPH NODES, RIGHT EXTERNAL ILIAC; BIOPSY:
- BENIGN ADIPOSE TISSUE.
- NO LYMPH NODES ARE IDENTIFIED IN THE ENTIRELY SUBMITTED SPECIMEN.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Source: NCI Genomic Data Commons file b144b129-e0e3-4e80-88aa-db6d73238a9e (TCGA-AP-A0LO.DC0116C2-788E-46F5-A4AC-115D857C1F85.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).